Somatic mutation profile of tumor specimen TCGA-AA-3662-01A (aliquot TCGA-AA-3662-01A-01D-1719-10) from TCGA case TCGA-AA-3662, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 80.9 years (29,554 days).
Specimen TCGA-AA-3662-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f64047c9-f353-49b6-8776-1c6089f8ce6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3662-11A (Solid Tissue Normal), aliquot TCGA-AA-3662-11A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c3de7e7-9e61-41f9-9f57-ebe50d6d8875

The open-access MAF lists 86 somatic variants for this specimen: 64 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 21, Nonsense Mutation 5, Intron 1, Frame Shift Del 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 20/39 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.2663C>T p.T888M | Missense Mutation (SNP) | VAF 63/120 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as rs200992288, COSV62321599; called by muse, mutect2, varscan2
- ADPGK | c.1268G>T p.R423L | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV61175433; called by muse, mutect2, varscan2
- AFF2 | c.1320G>T p.K440N | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV53984203; called by muse, mutect2, varscan2
- ALG13 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99322116; called by muse, mutect2, varscan2
- AMY1C | c.940C>T p.H314Y | Missense Mutation (SNP) | VAF 63/410 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64407658; called by muse, mutect2, varscan2
- AR | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.693); catalogued as COSV65964842; called by muse, mutect2, varscan2
- C10orf120 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.364); catalogued as COSV61492270; called by muse, mutect2, varscan2
- C12orf50 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 40/94 reads (43%) | catalogued as COSV53895565; called by muse, mutect2, varscan2
- CACNA1E | c.4372C>T p.R1458C | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs774399787, COSV62435602; called by muse, mutect2, varscan2
- CADPS | c.2149G>A p.A717T | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs768666285, COSV51873631; called by muse, mutect2, varscan2
- CAPN6 | c.975G>T p.M325I | Missense Mutation (SNP) | VAF 80/287 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as COSV60697261; called by muse, mutect2, varscan2
- CDC25A | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56772616; called by muse, mutect2, varscan2
- CDH23 | c.2939C>T p.T980M | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs535416598, COSV54955861; called by muse, mutect2, varscan2
- CFAP54 | c.5924C>T p.P1975L | Missense Mutation (SNP) | VAF 90/335 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as rs764964729, COSV100733146; called by muse, mutect2, varscan2
- DMXL2 | c.4114G>T p.V1372L | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51858089; called by muse, mutect2, varscan2
- EMD | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 64/334 reads (19%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs782057378, COSV63962134; called by muse, mutect2, varscan2
- F13B | c.404G>C p.C135S | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66376011; called by muse, mutect2, varscan2
- FLNC | c.5996G>A p.R1999Q | Missense Mutation (SNP) | VAF 100/168 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.193); catalogued as rs1346364708, COSV57953622; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMR1 | c.1322T>C p.L441S | Missense Mutation (SNP) | VAF 57/259 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99503240; called by muse, varscan2
- GALNT13 | c.340C>A p.L114I | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV67240575; called by muse, mutect2, varscan2
- GDF6 | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 51/512 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54625724; called by muse, mutect2, varscan2
- GOLGA5 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1365761178, COSV50836612; called by muse, mutect2, varscan2
- GRIK4 | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771623867, COSV70805576; called by muse, mutect2, varscan2
- H2AC13 | c.49A>G p.T17A | Missense Mutation (SNP) | VAF 82/449 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1476017292, COSV100704312, COSV100704367; called by muse, mutect2, varscan2
- HCN3 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.184); catalogued as COSV61362744; called by muse, mutect2, varscan2
- IGSF9B | c.2945C>T p.P982L | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs375067578; called by muse, mutect2, varscan2
- KCNIP3 | c.470T>A p.I157N | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV54673807; called by muse, mutect2, varscan2
- KLHL25 | c.968A>G p.K323R | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV61996779; called by muse, mutect2, varscan2
- KMT2C | c.3739A>T p.K1247* | Nonsense Mutation (SNP) | VAF 297/498 reads (60%) | catalogued as COSV100071327; called by muse, mutect2, varscan2
- KRT13 | c.1241C>A p.A414D | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV55841810; called by muse, mutect2, varscan2
- LHCGR | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); catalogued as COSV54304362; called by muse, mutect2, varscan2
- MAGEB4 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 47/272 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs770408937, COSV66775187; called by muse, mutect2, varscan2
- MAGEC1 | c.442C>A p.P148T | Missense Mutation (SNP) | VAF 81/307 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV53582817; called by muse, mutect2
- MASTL | c.1295G>A p.G432E | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60912973; called by muse, mutect2, varscan2
- MRPL19 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.694); catalogued as COSV62568268; called by muse, mutect2, varscan2
- MUC5AC | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0.01); catalogued as rs1357774544, COSV100650586; called by muse, mutect2, varscan2
- NLRP4 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 30/58 reads (52%) | catalogued as COSV56712322, COSV56720587; called by muse, mutect2, varscan2
- NPHP4 | c.4024G>A p.E1342K | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100976866; called by muse, mutect2, varscan2
- OBSL1 | c.4358G>A p.R1453Q | Missense Mutation (SNP) | VAF 63/278 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs1197623916, COSV54711127; called by muse, mutect2, varscan2
- OPRK1 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 56/285 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs760499924, COSV55568344; called by muse, mutect2, varscan2
- OR2T12 | c.622C>A p.P208T | Missense Mutation (SNP) | VAF 263/1145 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV58779969; called by muse, mutect2, varscan2
- OR2T33 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 106/531 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV58818376; called by muse, mutect2, varscan2
- OR5F1 | c.677T>C p.F226S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV104376642, COSV53549231; called by muse, mutect2, varscan2
- PCDH10 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.348); catalogued as rs1166212333, COSV99993065; called by muse, varscan2
- RIDA | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs1174760991, COSV54705777; called by muse, mutect2
- SEC31A | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52352776; called by muse, mutect2, varscan2
- SETD1A | c.2049G>T p.Q683H | Missense Mutation (SNP) | VAF 133/254 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV52693437; called by muse, mutect2, varscan2
- SKAP1 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.29); catalogued as rs1398260208, COSV100411729; called by muse, mutect2, varscan2
- SLC4A8 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 136/318 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.168); catalogued as rs200633626, COSV100176327, COSV60659243; called by muse, mutect2, varscan2
- SLTM | c.812T>C p.I271T | Missense Mutation (SNP) | VAF 165/347 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.276); catalogued as COSV51059566; called by muse, mutect2, varscan2
- SMAD9 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1483291649, COSV63205115, COSV63205817; called by muse, mutect2, varscan2
- SRGAP1 | c.160C>T p.R54* | Nonsense Mutation (SNP) | VAF 44/96 reads (46%) | catalogued as COSV61904504; called by muse, mutect2, varscan2
- TAAR5 | c.488C>A p.A163E | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV57800020; called by muse, mutect2, varscan2
- TIAM1 | c.1598C>T p.T533M | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770550744, COSV54578878; called by muse, mutect2, varscan2
- TNR | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.827); catalogued as rs201187422, COSV54915792; called by muse, mutect2, varscan2
- TNXB | c.4555G>A p.V1519M (on ENST00000647633; = p.V1272M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.47); catalogued as rs749925578, COSV64475090; called by muse, mutect2, varscan2
- TRIB2 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1346973390, COSV50224004; called by muse, mutect2, varscan2
- VCAN | c.4190C>A p.A1397E | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV54118905; called by muse, mutect2, varscan2
- ZMYND8 | c.1060C>T p.R354C (on ENST00000311275 / NM_001363741.2; = p.R374C on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/230 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs746337186, COSV53684265; called by muse, mutect2, varscan2
- ZNF626 | c.855C>A p.Y285* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV74131172; called by muse, mutect2, varscan2
- APC | c.4051dup p.A1351Gfs*3 | Frame Shift Ins (INS) | VAF 86/140 reads (61%) | called by mutect2, pindel, varscan2
- GNAT1 | c.29del p.K10Sfs*10 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | called by mutect2, pindel, varscan2
- PARPBP | c.770_772del p.I257del | In Frame Del (DEL) | VAF 13/52 reads (25%) | called by pindel, varscan2
- AMBRA1 | c.2988C>T p.N996= (on ENST00000458649 / NM_001367468.1; = p.N906= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs1371448924, COSV54063930; called by muse, mutect2, varscan2
- ATCAY | c.741C>A p.I247= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV100008683; called by muse, mutect2, varscan2
- ATP2A1 | c.2229C>T p.I743= | Silent (SNP) | VAF 94/191 reads (49%) | catalogued as COSV62871279; called by muse, mutect2, varscan2
- AZGP1 | c.393C>T p.S131= | Silent (SNP) | VAF 101/273 reads (37%) | catalogued as rs777569319, COSV52796934; called by muse, mutect2, varscan2
- BBS9 | c.1563A>G p.R521= (on ENST00000242067 / NM_001348036.1; = p.R481= on NM_014451.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/182 reads (18%) | catalogued as COSV99627815; called by muse, mutect2, varscan2
- CBX8 | c.1077G>A p.E359= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV53937841; called by muse, mutect2, varscan2
- CFAP61 | c.483G>A p.P161= | Silent (SNP) | VAF 88/196 reads (45%) | catalogued as rs369465869; called by muse, varscan2
- COL6A3 | c.4734C>T p.I1578= | Silent (SNP) | VAF 44/177 reads (25%) | catalogued as rs774809714, COSV55114232; called by muse, mutect2, varscan2
- DAB2IP | c.3420G>A p.S1140= (on ENST00000408936; = p.S1112= on NM_032552.3) | Silent (SNP) | VAF 60/125 reads (48%) | catalogued as rs753664017, COSV52269781; called by muse, mutect2, varscan2
- EN1 | c.936C>T p.A312= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs1478080942, COSV54632837; called by muse, mutect2
- GLDC | c.2832G>T p.P944= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100394050; called by muse, mutect2
- NRSN1 | c.270C>T p.I90= | Silent (SNP) | VAF 171/336 reads (51%) | catalogued as rs770598939, COSV65893738; called by muse, mutect2, varscan2
- OPRM1 | c.903C>T p.Y301= | Silent (SNP) | VAF 134/626 reads (21%) | catalogued as rs200986335, COSV57676566, COSV57682130; called by muse, mutect2, varscan2
- OR8D1 | c.132C>A p.G44= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as COSV63443203; called by muse, mutect2, varscan2
- PTPRS | c.477C>T p.S159= | Silent (SNP) | VAF 265/386 reads (69%) | catalogued as rs201540749, COSV53640224, COSV99510745; called by muse, mutect2, varscan2
- RAG1 | c.282C>T p.N94= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs148700564; called by muse, mutect2, varscan2
- RP1L1 | c.6174G>A p.P2058= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as rs200660179, COSV66751963; ClinVar: benign; called by muse, mutect2, varscan2
- SFMBT1 | c.6C>T p.N2= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as rs750153445, COSV56252330, COSV56254487; called by muse, mutect2, varscan2
- STARD13 | c.2926C>T p.L976= (on ENST00000336934 / NM_001243476.3; = p.L858= on NM_052851.3) | Silent (SNP) | VAF 211/387 reads (55%) | catalogued as COSV55237789; called by muse, mutect2, varscan2
- TBC1D8 | c.2410C>A p.R804= | Silent (SNP) | VAF 40/85 reads (47%) | catalogued as COSV65217443; called by muse, mutect2, varscan2
- ZNF609 | c.1899A>G p.E633= | Silent (SNP) | VAF 46/182 reads (25%) | catalogued as COSV58591503; called by mutect2, varscan2
- MACF1 | c.15832-9971A>C | Intron (SNP) | VAF 60/109 reads (55%) | catalogued as COSV57149132; called by muse, mutect2, varscan2
